Somatic mutation profile of tumor specimen MMRF_2442_1_BM_CD138pos (aliquot MMRF_2442_1_BM_CD138pos_T1_KHS5U_L11593) from MMRF case MMRF_2442, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.7 years (22,918 days).
Specimen MMRF_2442_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f6fba34-e792-44fe-8281-ebed89a65b86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2442_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2442_1_PB_Whole_C2_KHS5U_L11594; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0da52a2e-7b7f-498c-acf4-13e4f470edb4

The open-access MAF lists 104 somatic variants for this specimen: 42 protein-altering or splice-affecting, 16 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 21, Intron 18, Silent 16, 5'UTR 4, Frame Shift Del 2, Nonsense Mutation 2, 3'Flank 1, 5'Flank 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANO3 | c.2794G>A p.A932T | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs770630092, COSV56787191; called by muse, varscan2
- AP1M2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754237081, COSV51569463; called by muse, mutect2, varscan2
- ARSI | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 95/283 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs199522076, COSV60817762; called by muse, mutect2, varscan2
- BAHCC1 | c.4297G>A p.D1433N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs782331411; called by muse, mutect2, varscan2
- CCDC80 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 88/343 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756967937, COSV52817165; called by muse, mutect2, varscan2
- CNTNAP2 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as rs368905425, COSV62202275; called by muse, mutect2, varscan2
- DISP3 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53836957; called by muse, mutect2
- FADD | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1371367785, COSV99042419; called by muse, mutect2, varscan2
- FAM47B | c.1847G>A p.W616* | Nonsense Mutation (SNP) | VAF 100/190 reads (53%) | catalogued as rs1242540642; called by muse, mutect2, varscan2
- IGHV2-70 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs373039668; called by muse, varscan2
- IRGC | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs752810297, COSV54984590; called by muse, mutect2, varscan2
- MAP2 | c.2637G>T p.L879F | Missense Mutation (SNP) | VAF 93/265 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52295024; called by muse, mutect2, varscan2
- NCKAP1 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as rs771788516; called by muse, mutect2, varscan2
- NRAS | c.190T>A p.Y64N | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54744579, COSV54745979; called by muse, mutect2, varscan2
- OR5R1 | c.954A>T p.L318F | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.021); catalogued as rs141438285; called by muse, mutect2, varscan2
- PHLDB3 | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 75/107 reads (70%) | catalogued as rs779256345; called by muse, mutect2, varscan2
- SCN9A | c.5918G>T p.R1973I (on ENST00000303354; = p.R1962I on NM_002977.3) | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.066); catalogued as rs771903438, COSV100313525; called by muse, mutect2, varscan2
- SUOX | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs201830071; called by muse, mutect2, varscan2
- TADA3 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 94/243 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as rs771190912; called by muse, mutect2, varscan2
- UBR7 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1422869886; called by muse, mutect2, varscan2
- ARSD | c.265T>C p.C89R | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CATSPERE | c.2711T>C p.V904A | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSPG4 | c.2206G>A p.V736M | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CTNNA2 | c.49T>A p.L17M | Missense Mutation (SNP) | VAF 270/891 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DNAAF5 | c.1517_1518del p.S506Cfs*4 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- FAM181A | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- H3C11 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 134/330 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- IRX4 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LINS1 | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 12/353 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC16 | c.30146C>A p.S10049Y | Missense Mutation (SNP) | VAF 102/188 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- MUC16 | c.10372A>G p.T3458A | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- NOTCH3 | c.4424G>A p.C1475Y | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCGF3 | c.402_405del p.N134Kfs*21 | Frame Shift Del (DEL) | VAF 24/106 reads (23%) | called by pindel, varscan2
- POU3F2 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- STXBP5 | c.3317T>A p.L1106Q (on ENST00000321680 / NM_001127715.2; = p.L1070Q on NM_139244.4) | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.394); called by muse, mutect2
- TENT5C | c.655T>C p.F219L | Missense Mutation (SNP) | VAF 86/271 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TNPO1 | c.1092_1097del p.E364_E365del | In Frame Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- ZDHHC14 | c.407A>G p.D136G | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFP62 | c.581A>T p.E194V (on ENST00000502412 / NM_001377944.1; = p.E161V on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 125/410 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF331 | c.1300A>G p.S434G | Missense Mutation (SNP) | VAF 86/351 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF408 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- AC098582.1 | c.1435C>T p.L479= | Silent (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- B3GAT1 | c.222G>A p.T74= | Silent (SNP) | VAF 109/288 reads (38%) | catalogued as rs1432087783, COSV56997752; called by muse, mutect2, varscan2
- CTBP2 | c.480G>A p.T160= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs747716967, COSV58333471; called by muse, mutect2, varscan2
- DCLK2 | c.1449G>A p.S483= | Silent (SNP) | VAF 74/215 reads (34%) | catalogued as rs374196545; called by muse, mutect2, varscan2
- FNDC1 | c.5377C>A p.R1793= | Silent (SNP) | VAF 48/121 reads (40%) | catalogued as rs763337015, COSV51936598; called by muse, mutect2, varscan2
- GPD2 | c.411A>C p.V137= | Silent (SNP) | VAF 59/146 reads (40%) | called by muse, mutect2, varscan2
- GPR157 | c.564G>A p.L188= | Silent (SNP) | VAF 14/249 reads (6%) | catalogued as rs750196783; called by muse, mutect2
- IAH1 | c.702A>G p.A234= | Silent (SNP) | VAF 41/380 reads (11%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 56/160 reads (35%) | catalogued as rs367953381; called by muse, varscan2
- IGLL5 | c.156T>C p.P52= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs576960332; called by muse, mutect2, varscan2
- MNS1 | c.624G>A p.Q208= | Silent (SNP) | VAF 38/97 reads (39%) | called by muse, mutect2, varscan2
- MUC17 | c.5184T>C p.R1728= | Silent (SNP) | VAF 30/634 reads (5%) | catalogued as rs1562810179, COSV60298588; called by muse, mutect2
- NLRP12 | c.2739C>T p.C913= | Silent (SNP) | VAF 43/184 reads (23%) | called by muse, mutect2, varscan2
- R3HDM4 | c.378C>T p.S126= | Silent (SNP) | VAF 47/66 reads (71%) | catalogued as rs1257567091, COSV64292743; called by muse, mutect2, varscan2
- TACSTD2 | c.786C>T p.D262= | Silent (SNP) | VAF 134/304 reads (44%) | called by muse, mutect2, varscan2
- TRPM7 | c.5061C>A p.A1687= | Silent (SNP) | VAF 48/321 reads (15%) | called by muse, mutect2, varscan2
- ABI3BP | c.1064-468C>T | Intron (SNP) | VAF 20/254 reads (8%) | called by muse, mutect2
- C2orf81 | c.*56G>A | 3'UTR (SNP) | VAF 43/102 reads (42%) | called by muse, mutect2, varscan2
- CLEC1B | c.-119G>A | 5'UTR (SNP) | VAF 19/537 reads (4%) | called by muse, mutect2
- CNOT9 | c.*828del | 3'UTR (DEL) | VAF 51/166 reads (31%) | called by mutect2, pindel, varscan2
- CNTN5 | c.278-29T>A | Intron (SNP) | VAF 28/144 reads (19%) | called by mutect2, varscan2
- COG6 | c.*2923A>C | 3'UTR (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- CREM | c.121-8095G>C | Intron (SNP) | VAF 9/137 reads (7%) | called by muse, mutect2
- DENND1B | c.*4037A>G | 3'UTR (SNP) | VAF 72/155 reads (46%) | catalogued as rs1003496084; called by muse, mutect2, varscan2
- EML2 | c.1122+135C>A | Intron (SNP) | VAF 35/123 reads (28%) | called by muse, mutect2, varscan2
- EPHB4 | c.*460T>A | 3'UTR (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
- ERGIC1 | c.376-3611T>G | Intron (SNP) | VAF 16/497 reads (3%) | called by muse, mutect2
- ETFA | c.-44C>T | 5'UTR (SNP) | VAF 25/124 reads (20%) | catalogued as rs558025844; called by muse, mutect2, varscan2
- FIGN | c.*2526T>C | 3'UTR (SNP) | VAF 35/90 reads (39%) | catalogued as rs530124182; called by muse, mutect2, varscan2
- GCA | c.454+55A>T | Intron (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- IL31RA | c.1501+291C>T | Intron (SNP) | VAF 33/84 reads (39%) | catalogued as rs781090762; called by muse, mutect2, varscan2
- INTS7 | c.510-171T>C | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as rs1241874420; called by muse, mutect2, varscan2
- KDM2B | c.932-3637C>T | Intron (SNP) | VAF 94/197 reads (48%) | catalogued as rs1555306525; called by muse, mutect2, varscan2
- KIF1B | c.1181-58G>T | Intron (SNP) | VAF 36/124 reads (29%) | called by muse, mutect2
- KRT8P11 | n.1407T>A | RNA (SNP) | VAF 33/167 reads (20%) | called by muse, mutect2, varscan2
- LPGAT1 | chr1:211746516 del T | 3'Flank (DEL) | VAF 66/155 reads (43%) | catalogued as rs1454394478; called by mutect2, pindel, varscan2
- MAML3 | c.-722C>T | 5'UTR (SNP) | VAF 47/108 reads (44%) | called by muse, mutect2
- MRPS18B | c.*133G>A | 3'UTR (SNP) | VAF 6/18 reads (33%) | catalogued as rs759210306; called by muse, varscan2
- MTMR10 | c.-70G>A | 5'UTR (SNP) | VAF 11/102 reads (11%) | catalogued as rs1007543014, COSV71188902; called by muse, mutect2, varscan2
- NARF | c.769+614T>C | Intron (SNP) | VAF 117/283 reads (41%) | catalogued as rs940099834; called by muse, mutect2, varscan2
- NDEL1 | c.*420G>T | 3'UTR (SNP) | VAF 65/439 reads (15%) | called by muse, mutect2, varscan2
- NECTIN1 | c.79+14735G>A | Intron (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- PPFIA4 | c.*101G>T | 3'UTR (SNP) | VAF 8/206 reads (4%) | called by muse, mutect2
- PPFIBP1 | c.270+1722C>T | Intron (SNP) | VAF 52/144 reads (36%) | catalogued as rs947735479; called by muse, mutect2, varscan2
- PTN | c.*312dup | 3'UTR (INS) | VAF 19/71 reads (27%) | catalogued as rs940455424; called by mutect2, pindel, varscan2
- PTPN21 | c.*162G>A | 3'UTR (SNP) | VAF 21/53 reads (40%) | catalogued as rs949679790, COSV60849567; called by muse, mutect2, varscan2
- RHOJ | c.*1637C>T | 3'UTR (SNP) | VAF 18/37 reads (49%) | catalogued as rs532203007; called by muse, mutect2, varscan2
- RIOK3 | c.*1388T>C | 3'UTR (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- RPUSD3 | c.262+61G>A | Intron (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- S1PR2 | c.-43+752C>A | Intron (SNP) | VAF 105/192 reads (55%) | called by muse, mutect2, varscan2
- SKIL | c.*815T>C | 3'UTR (SNP) | VAF 29/97 reads (30%) | catalogued as rs958092339; called by muse, mutect2, varscan2
- STX6 | c.*694G>C | 3'UTR (SNP) | VAF 8/183 reads (4%) | called by muse, mutect2
- TCP11L2 | c.772+640del | Intron (DEL) | VAF 24/93 reads (26%) | called by mutect2, pindel, varscan2
- THADA | c.2311+2017C>T | Intron (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- TIPARP | c.*741C>T | 3'UTR (SNP) | VAF 28/149 reads (19%) | catalogued as rs565705653; called by muse, mutect2, varscan2
- TMTC1 | c.*554G>C | 3'UTR (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- UBXN4 | chr2:135741826 C>T | 5'Flank (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- UBXN4 | c.*1242_*1243insA | 3'UTR (INS) | VAF 32/98 reads (33%) | called by mutect2, pindel, varscan2
- YBX2 | c.335+204G>C | Intron (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- YTHDF1 | c.*417C>A | 3'UTR (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- ZNF621 | c.*2510G>T | 3'UTR (SNP) | VAF 56/143 reads (39%) | called by muse, mutect2, varscan2
- ZNF662 | c.*1686G>A | 3'UTR (SNP) | VAF 20/79 reads (25%) | catalogued as rs781258158, COSV60242856; called by muse, mutect2, varscan2
